CPTAC case C3N-02675 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/63583ff6-1a97-425c-9b8a-63880e87c038

Demographics
Sex at birth: male; Race: white; Year of birth: 1948; Vital status: Dead; Days to death: 1,338 days (3.7 years); Year of death: 2021; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 69.4 years (25,361 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R2; Last known disease status: With tumor; Days to last known disease status: 1,338 days (3.7 years); Progression or recurrence: yes; Days to recurrence: 750 days (2.1 years); Days to last follow up: 1,338 days (3.7 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 1.7 cm (a second GDC size field records 7 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (5 entries)
- Days to follow up: 354 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 354 days; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 449 days (1.2 years); Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 750 days (2.1 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 1,057 days (2.9 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 1,338 days (3.7 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 84 kg; Height: 176 cm; BMI: 27.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Cigarettes per day: 20; Tobacco smoking onset year: 1997; Tobacco smoking quit year: 2017; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 20.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02675-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 1 day; Initial weight: 221 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02675-24: Section location: Right Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 20.
- Sample C3N-02675-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 1 day; Initial weight: 175 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02675-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 1 day; Method of sample procurement: Blood Draw.
